Somatic mutation profile of tumor specimen 0DDTE4 from CCDI case PBBNYL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 15.3 years (5,582 days).
Specimen 0DDTE4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d23988ff-f9d9-44db-a8b0-2d71e265a7a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDTE5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d1bf86f-d481-44c4-b0b7-204dc92ba0ce

The open-access MAF lists 13 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 4, Silent 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 72/1236 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2
- CHRM2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 277/1449 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as rs774760812, COSV100280682; called by muse, mutect2, varscan2
- AGFG1 | c.1622C>G p.P541R | Missense Mutation (SNP) | VAF 70/769 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCNB3 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 199/1025 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNG1 | c.963C>T p.A321= | Silent (SNP) | VAF 67/231 reads (29%) | catalogued as rs1281286853, COSV65368666; called by muse, mutect2, varscan2
- NAV2 | c.2422C>T p.L808= (on ENST00000396087 / NM_001244963.2; = p.L785= on NM_145117.5) | Silent (SNP) | VAF 161/739 reads (22%) | catalogued as rs781726630; called by muse, mutect2, varscan2
- PCDH7 | c.2424G>A p.P808= | Silent (SNP) | VAF 248/1398 reads (18%) | catalogued as rs746447440; called by muse, mutect2, varscan2
- STOX2 | c.1566C>T p.T522= | Silent (SNP) | VAF 29/694 reads (4%) | called by muse, mutect2
- ABITRAM | c.-4C>A | 5'UTR (SNP) | VAF 47/322 reads (15%) | catalogued as rs1268468540; called by muse, mutect2, varscan2
- NONO | c.944-99G>C | Intron (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- NONO | c.1132-82T>G | Intron (SNP) | VAF 49/233 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+26G>A | Intron (SNP) | VAF 19/264 reads (7%) | catalogued as rs1457050126; called by muse, mutect2
- WRAP73 | c.923-81A>T | Intron (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
